Somatic mutation profile of tumor specimen C3N-01651-01 (aliquot CPT0088690009) from CPTAC case C3N-01651, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 58.8 years (21,464 days).
Specimen C3N-01651-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 969b7ea9-f67b-4a90-9f85-075af43264d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01651-31 (Blood Derived Normal), aliquot CPT0088750002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3efac22b-e9dc-494c-ba1b-b35055311bee

The open-access MAF lists 74 somatic variants for this specimen: 52 protein-altering or splice-affecting, 14 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 14, Intron 6, Nonsense Mutation 3, Frame Shift Del 2, 5'Flank 1, RNA 1, In Frame Del 1, Splice Region 1, Nonstop Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.274G>T p.D92Y | Missense Mutation (SNP) | VAF 119/354 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554898067, CM1111457, COSV64291669, COSV64295080, COSV64295612; ClinVar: uncertain significance; called by muse, varscan2
- VHL | c.263G>C p.W88S | Missense Mutation (SNP) | VAF 79/313 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs119103277, CM951277, CM995326, HX971376, COSV56543204, COSV56545932, COSV56566114; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRG4 | c.3977G>C p.G1326A | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.336); catalogued as COSV54957612; called by muse, mutect2
- AMPD1 | c.679C>A p.P227T | Missense Mutation (SNP) | VAF 146/445 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62414954, COSV62417076, COSV62418845; called by muse, mutect2, varscan2
- C1orf159 | c.430G>A p.V144M (on ENST00000379339 / NM_001330306.2; = p.V108M on NM_017891.5) | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs750931700, COSV99618764; called by muse, mutect2, varscan2
- CERKL | c.790G>A p.E264K (on ENST00000339098 / NM_001030311.2; = p.E238K on NM_201548.5) | Missense Mutation (SNP) | VAF 147/671 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs532973636, COSV100183708; called by muse, mutect2, varscan2
- CYP11B2 | c.439G>C p.D147H | Missense Mutation (SNP) | VAF 68/560 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV59995853; called by muse, mutect2, varscan2
- DSEL | c.2466G>T p.W822C | Missense Mutation (SNP) | VAF 71/271 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144626811, COSV100026027; called by muse, mutect2, varscan2
- EP400 | c.6476C>T p.A2159V | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs755946961; called by muse, varscan2
- GRM8 | c.1567G>A p.G523R | Missense Mutation (SNP) | VAF 78/247 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58875789; called by muse, mutect2, varscan2
- HCRTR1 | c.883A>T p.K295* | Nonsense Mutation (SNP) | VAF 39/260 reads (15%) | catalogued as COSV65485623; called by muse, mutect2, varscan2
- HPSE2 | c.839G>T p.G280V | Missense Mutation (SNP) | VAF 152/419 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as rs774034388; called by muse, mutect2, varscan2
- ITGA4 | c.2825G>C p.G942A | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59203927; called by muse, mutect2, varscan2
- KDM5C | c.2041C>T p.R681* | Nonsense Mutation (SNP) | VAF 136/241 reads (56%) | catalogued as COSV64762991; called by muse, mutect2, varscan2
- MPPED2 | c.414C>A p.F138L | Missense Mutation (SNP) | VAF 45/385 reads (12%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.975); catalogued as COSV63900339; called by muse, mutect2, varscan2
- MUC16 | c.26475C>G p.H8825Q | Missense Mutation (SNP) | VAF 88/379 reads (23%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.001); catalogued as rs367975513; called by muse, mutect2, varscan2
- POFUT1 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs766503770; called by muse, mutect2, varscan2
- PROM1 | c.2277C>A p.F759L | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.011); catalogued as COSV101477081; called by muse, mutect2, varscan2
- PRXL2A | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100939814; called by muse, mutect2, varscan2
- RNASE10 | c.344C>T p.T115I | Missense Mutation (SNP) | VAF 61/258 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.037); catalogued as COSV60517437; called by muse, mutect2, varscan2
- RNF214 | c.1585G>A p.A529T | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs774814849, COSV56118278; called by muse, mutect2, varscan2
- ANOS1 | c.995G>T p.W332L | Missense Mutation (SNP) | VAF 185/336 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- BPTF | c.3068G>A p.G1023D | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C2CD5 | c.2194A>G p.R732G | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- CAMSAP3 | c.3272A>G p.D1091G | Missense Mutation (SNP) | VAF 43/240 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- CARD9 | c.503G>A p.C168Y | Missense Mutation (SNP) | VAF 93/259 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- CCL3L3 | c.19G>T p.A7S | Missense Mutation (SNP) | VAF 146/274 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- CLCA1 | c.2127G>C p.W709C | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.264); called by muse, varscan2
- CNTRL | c.5692C>T p.L1898F | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- COL11A2 | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 116/518 reads (22%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CPOX | c.670A>G p.S224G | Missense Mutation (SNP) | VAF 78/323 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- EFTUD2 | c.27dup p.G10Wfs*9 | Frame Shift Ins (INS) | VAF 51/178 reads (29%) | called by mutect2, pindel, varscan2
- EXT2 | c.1581T>A p.D527E (on ENST00000343631; = p.D560E on NM_000401.3) | Missense Mutation (SNP) | VAF 87/302 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- F2RL1 | c.1098_1106del p.V367_Q369del | In Frame Del (DEL) | VAF 51/275 reads (19%) | called by mutect2, pindel, varscan2
- FKBP15 | c.254+6T>A | Splice Region (SNP) | VAF 48/153 reads (31%) | called by muse, mutect2, varscan2
- FLG2 | c.3335C>T p.S1112F | Missense Mutation (SNP) | VAF 38/305 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- IGHG2 | c.303del p.K101Nfs*31 | Frame Shift Del (DEL) | VAF 43/326 reads (13%) | called by mutect2, pindel, varscan2
- LRRC61 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 51/356 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR5AU1 | c.936A>C p.*312Cext*18 | Nonstop Mutation (SNP) | VAF 20/84 reads (24%) | called by muse, mutect2, varscan2
- PBRM1 | c.4812del p.L1605Ffs*7 (on ENST00000296302 / NM_001366071.2; = p.L1498Ffs*7 on NM_018313.5) | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- PDS5A | c.3266A>C p.K1089T | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RNF122 | c.413C>G p.A138G | Missense Mutation (SNP) | VAF 46/185 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- RPL19 | c.188G>T p.C63F | Missense Mutation (SNP) | VAF 33/270 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SETD2 | c.5213T>A p.L1738* | Nonsense Mutation (SNP) | VAF 69/190 reads (36%) | called by muse, mutect2, varscan2
- SLC2A4RG | c.806T>C p.M269T | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC4A4 | c.1637A>T p.N546I (on ENST00000264485 / NM_001098484.3; = p.N502I on NM_003759.4) | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- SNRNP200 | c.1060C>A p.P354T | Missense Mutation (SNP) | VAF 144/546 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, varscan2
- STX17 | c.43C>G p.P15A | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.027); called by muse, mutect2
- SYTL3 | c.1491T>A p.D497E (on ENST00000611299 / NM_001242394.1; = p.D429E on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- TMC5 | c.2530T>C p.S844P (on ENST00000396229 / NM_001105248.1; = p.S598P on NM_024780.5) | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- USP15 | c.8A>T p.E3V | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WFDC9 | c.188C>G p.P63R | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- BRPF1 | c.2208A>T p.A736= | Silent (SNP) | VAF 99/236 reads (42%) | called by muse, mutect2, varscan2
- C11orf96 | c.180A>G p.Q60= | Silent (SNP) | VAF 25/93 reads (27%) | called by muse, mutect2, varscan2
- COL6A5 | c.144C>T p.F48= | Silent (SNP) | VAF 32/104 reads (31%) | catalogued as rs776749715, COSV55193211; called by muse, mutect2, varscan2
- CSMD3 | c.4131C>T p.I1377= (on ENST00000297405 / NM_001363185.1; = p.I1273= on NM_052900.3) | Silent (SNP) | VAF 31/223 reads (14%) | catalogued as rs752937032, COSV52290691; called by muse, mutect2, varscan2
- ENPP4 | c.678A>T p.L226= | Silent (SNP) | VAF 52/200 reads (26%) | called by muse, mutect2, varscan2
- FSD1 | c.1212G>A p.T404= | Silent (SNP) | VAF 88/423 reads (21%) | catalogued as rs776188536, COSV55698498, COSV99697042; called by muse, mutect2, varscan2
- HECTD1 | c.1296T>C p.H432= | Silent (SNP) | VAF 31/158 reads (20%) | called by muse, mutect2, varscan2
- KRT75 | c.462G>A p.K154= | Silent (SNP) | VAF 82/300 reads (27%) | catalogued as COSV52872876; called by muse, mutect2, varscan2
- PCDHGB6 | c.1759C>T p.L587= | Silent (SNP) | VAF 84/346 reads (24%) | called by muse, mutect2, varscan2
- RGS22 | c.3504C>T p.D1168= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs372450445; called by mutect2, varscan2
- TOGARAM2 | c.705C>A p.I235= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as COSV65421064; called by muse, mutect2, varscan2
- TRIM58 | c.891C>T p.P297= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as rs745534672, COSV63572003; called by mutect2, varscan2
- TTN | c.20073C>A p.L6691= (on ENST00000591111; = p.L5764= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 47/260 reads (18%) | called by muse, mutect2, varscan2
- ZNF491 | c.747G>T p.G249= | Silent (SNP) | VAF 22/128 reads (17%) | catalogued as COSV60057400; called by muse, mutect2, varscan2
- AC092675.1 | n.459-141C>G | Intron (SNP) | VAF 75/274 reads (27%) | called by muse, mutect2, varscan2
- ALDH1L1 | c.2654-9G>T | Intron (SNP) | VAF 60/254 reads (24%) | called by muse, mutect2, varscan2
- C2CD5 | c.177+44G>A | Intron (SNP) | VAF 36/138 reads (26%) | catalogued as rs753493910; called by muse, varscan2
- DLG5 | c.373+1134G>T | Intron (SNP) | VAF 88/295 reads (30%) | called by muse, mutect2, varscan2
- N4BP2L1 | c.307+28G>A | Intron (SNP) | VAF 85/243 reads (35%) | called by muse, mutect2, varscan2
- TSPAN32 | c.543+729G>C | Intron (SNP) | VAF 2/11 reads (18%) | called by muse, mutect2
- TUBB7P | n.910G>C | RNA (SNP) | VAF 58/394 reads (15%) | called by muse, varscan2
- ZBTB37 | chr1:173866939 G>T | 5'Flank (SNP) | VAF 30/179 reads (17%) | called by muse, mutect2, varscan2
